Somatic mutation profile of tumor specimen TCGA-RD-A7C1-01A (aliquot TCGA-RD-A7C1-01A-11D-A32N-08) from TCGA case TCGA-RD-A7C1, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 82.6 years (30,171 days).
Specimen TCGA-RD-A7C1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7bfc7b1-8293-48ad-ae9d-8b6b0d623e2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A7C1-10A (Blood Derived Normal), aliquot TCGA-RD-A7C1-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/213c09f2-e412-4b0b-9854-6ddedfa4c278

The open-access MAF lists 281 somatic variants for this specimen: 221 protein-altering or splice-affecting, 56 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 202, Silent 56, Nonsense Mutation 9, Splice Site 3, RNA 2, In Frame Del 2, Splice Region 2, Frame Shift Ins 1, Frame Shift Del 1, 5'UTR 1, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF3 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs556532781, COSV53047409; called by muse, mutect2, varscan2
- ABLIM2 | c.269T>G p.I90S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV99590566, COSV99590860; called by muse, mutect2
- ACR | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV99334570; called by muse, mutect2, varscan2
- ACTRT2 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 59/246 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs199702037, COSV65759312; called by muse, mutect2, varscan2
- ADAM23 | c.1169+1G>A p.X390_splice | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100008864; called by muse, mutect2, varscan2
- ADAM23 | c.2323A>G p.R775G | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100008865; called by muse, mutect2, varscan2
- ADAM7 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.999); catalogued as COSV99444365; called by muse, mutect2, varscan2
- ADAMTS19 | c.2150T>G p.L717R | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.36); catalogued as COSV50732503; called by muse, mutect2
- ADARB2 | c.1241A>T p.K414M | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101187334; called by muse, mutect2, varscan2
- ADGRB3 | c.64T>G p.F22V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs1561979192, COSV101001994; called by muse, mutect2, varscan2
- ADGRB3 | c.2975C>G p.A992G | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53250317, COSV99486918; called by muse, mutect2, varscan2
- AGAP2 | c.2263G>A p.G755R (on ENST00000547588 / NM_001122772.2; = p.G419R on NM_014770.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1027170769, COSV99224293; called by muse, mutect2, varscan2
- AIG1 | c.503G>C p.G168A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99264645; called by muse, mutect2, varscan2
- AL133500.1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated, low confidence (0.16); catalogued as rs751916691, COSV99860492; called by muse, varscan2
- AMPD1 | c.1360C>T p.H454Y | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100815257; called by muse, mutect2
- ANKRD30A | c.997G>T p.E333* (on ENST00000611781; = p.E277* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100654462; called by muse, mutect2, varscan2
- ANKRD30A | c.998A>G p.E333G (on ENST00000611781; = p.E277G on NM_052997.2) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as COSV100654463; called by muse, mutect2, varscan2
- ARHGAP12 | c.1270A>G p.T424A | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs756096661, COSV100260921; called by muse, mutect2, varscan2
- ARHGAP5 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781445770, COSV61538565; called by muse, mutect2, varscan2
- ASAP2 | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs553146291, COSV55632933, COSV99856882; called by muse, mutect2, varscan2
- ATG10 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs548892230, COSV56423393; called by muse, mutect2, varscan2
- ATP10B | c.3338T>A p.V1113E | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100515787; called by muse, mutect2, varscan2
- ATP4B | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767846093, COSV100089770; called by muse, mutect2, varscan2
- ATP5F1C | c.671A>C p.D224A | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV100184414; called by muse, mutect2, varscan2
- AZI2 | c.713A>T p.Q238L | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV99843770; called by muse, mutect2, varscan2
- BAZ2B | c.1830T>G p.D610E | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV100601025; called by muse, mutect2, varscan2
- BCL11B | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as rs557598154, COSV100595935; called by muse, mutect2
- BNIP2 | c.309A>C p.K103N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.474); catalogued as COSV99985909; called by muse, mutect2
- C8A | c.1742C>T p.T581M | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs143726641, COSV63484861; called by muse, mutect2, varscan2
- C9orf43 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV99928605; called by muse, mutect2, varscan2
- CABS1 | c.55A>T p.K19* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as rs968248490, COSV99909213; called by muse, mutect2, varscan2
- CACNA1B | c.6590C>T p.P2197L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99499923; called by muse, mutect2, varscan2
- CADM3 | c.388C>T p.P130S (on ENST00000368125 / NM_001127173.3; = p.P164S on NM_021189.5) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100930416; called by muse, mutect2
- CATSPER2 | c.419G>A p.W140* | Nonsense Mutation (SNP) | VAF 13/135 reads (10%) | catalogued as COSV100390999; called by muse, mutect2
- CCDC144A | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 112/251 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV100502202; called by muse, mutect2, varscan2
- CCDC42 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs942378045, COSV53447943; called by muse, mutect2, varscan2
- CCN4 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs34782842; called by muse, mutect2, varscan2
- CD1D | c.427A>C p.S143R | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV100939661; called by muse, mutect2, varscan2
- CD36 | c.592G>C p.V198L | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as COSV99987905; called by muse, mutect2, varscan2
- CDC42BPB | c.2639A>C p.Q880P | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100775621; called by muse, mutect2, varscan2
- CDH8 | c.287T>C p.I96T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.375); catalogued as COSV54857544; called by muse, mutect2, varscan2
- CDK11B | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.987); catalogued as COSV100478239; called by muse, mutect2, varscan2
- CENPF | c.6391G>A p.D2131N | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs181293702; called by muse, mutect2
- CEP152 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs755442860, COSV57859968; called by muse, mutect2, varscan2
- CFAP61 | c.3388C>T p.R1130W | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748459645, COSV99846692; called by muse, mutect2, varscan2
- CFH | c.293T>A p.L98H | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100661656; called by muse, varscan2
- CHL1 | c.3394A>C p.T1132P (on ENST00000397491 / NM_001253387.1; = p.T1148P on NM_006614.4) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99852378; called by muse, mutect2, varscan2
- CHRNB2 | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299746171, COSV100872687, COSV63807891; called by muse, mutect2, varscan2
- CLEC12A | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV100429696; called by muse, mutect2, varscan2
- CLIC2 | c.483C>G p.D161E | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100425753; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CNTN6 | c.2437A>T p.S813C | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100611866; called by muse, mutect2, varscan2
- COL12A1 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs764727126, COSV59392637; called by muse, mutect2, varscan2
- COL22A1 | c.4538G>T p.R1513L | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs200298766, COSV100278836, COSV57343458; called by muse, mutect2, varscan2
- CPSF1 | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs187194490; called by muse, mutect2, varscan2
- CRADD | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs563879626, COSV100257852; called by muse, mutect2, varscan2
- CRYGA | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs750806292, COSV100378668; called by muse, mutect2
- CSMD1 | c.4207C>A p.R1403S (on ENST00000520002; = p.R1402S on NM_033225.6) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100153859; called by muse, varscan2
- CSMD3 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99848100; called by muse, mutect2
- CTNNA2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751827909, COSV63554385; called by muse, mutect2
- CUBN | c.9208G>A p.V3070I | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs144314567, COSV100912272; called by muse, mutect2, varscan2
- CYFIP2 | c.2668C>T p.R890W (on ENST00000616178 / NM_001291722.2; = p.R865W on NM_014376.4) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs867115883, COSV56636365; called by muse, mutect2, varscan2
- CYP11B2 | c.62C>A p.A21E | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV59996457; called by muse, mutect2
- DACH2 | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV100913940; called by muse, mutect2, varscan2
- DCAF12L1 | c.1370A>C p.N457T | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100948078; called by muse, mutect2, varscan2
- DCC | c.3337G>C p.V1113L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.225); catalogued as COSV101473555; called by muse, mutect2, varscan2
- DMD | c.2113C>G p.P705A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99926313, COSV99926330; called by mutect2, varscan2
- DNAI3 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs149091067; called by muse, mutect2, varscan2
- DTX3 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99678035; called by muse, mutect2, varscan2
- EBF3 | c.1780C>T p.P594S (on ENST00000355311 / NM_001375392.1; = p.P549S on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.141); catalogued as rs1017481754, COSV100799622; called by muse, mutect2, varscan2
- EMSY | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1340348017, COSV100596084; called by muse, mutect2
- EPHA7 | c.773T>G p.V258G | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100992532, COSV65170191; called by muse, mutect2, varscan2
- ERCC6L | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 71/123 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as COSV100559269; called by muse, mutect2, varscan2
- F8 | c.2767T>G p.L923V | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV100811405; called by muse, mutect2, varscan2
- FAM155B | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs367802100, COSV99368690, COSV99368692; called by muse, mutect2, varscan2
- FANCM | c.3926A>T p.H1309L | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99951666; called by muse, mutect2, varscan2
- FDX1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs761435469, COSV99501940; called by muse, mutect2, varscan2
- FGFRL1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs773213801, COSV99294864; called by muse, mutect2, varscan2
- FLG | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 151/580 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs144799241; called by muse, mutect2, varscan2
- FN1 | c.5218G>A p.A1740T | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs753498044, COSV100118312; called by muse, mutect2, varscan2
- FOXI1 | c.376T>C p.Y126H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100089621; called by muse, mutect2
- FRAS1 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs367598897; ClinVar: uncertain significance; called by muse, mutect2
- FSD2 | c.290G>T p.R97I | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV100575298, COSV58011355; called by muse, mutect2
- GAPDHS | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 3/49 reads (6%) | catalogued as COSV55882892; called by muse, mutect2
- GMEB2 | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs991103616, COSV56605757, COSV99823467; called by muse, mutect2
- GPR142 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs745669503, COSV100171024; called by muse, mutect2, varscan2
- GPR50 | c.1331T>C p.V444A | Missense Mutation (SNP) | VAF 60/388 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as COSV99506686; called by muse, mutect2, varscan2
- GRIP1 | c.1256C>T p.S419F (on ENST00000359742 / NM_001379345.1; = p.S367F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as COSV54033721; called by muse, mutect2, varscan2
- GRM6 | c.2576A>G p.K859R | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV51451484, COSV99179959; called by muse, mutect2, varscan2
- H1-4 | c.477G>C p.K159N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV99175390; called by muse, mutect2, varscan2
- HERC1 | c.11297G>T p.G3766V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); catalogued as COSV101496925; called by muse, mutect2, varscan2
- HK1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV53857262; called by muse, mutect2, varscan2
- HPDL | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100588194; called by muse, mutect2
- HPX | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs201159600, COSV56419030; called by muse, mutect2, varscan2
- HTR3B | c.521A>C p.K174T | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV99492317; called by muse, mutect2, varscan2
- HYAL2 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.716); catalogued as rs1411759105, COSV99222884; called by muse, mutect2, varscan2
- IARS1 | c.2657A>C p.N886T | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100986737; called by muse, mutect2, varscan2
- IFT52 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs184017871, COSV100887679; called by muse, mutect2, varscan2
- INTS6 | c.2580A>C p.K860N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV100247273; called by muse, mutect2, varscan2
- ITGA2B | c.1820C>T p.T607M | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as rs539187844, COSV52236037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGAM | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs762226869, COSV99793163; called by muse, mutect2, varscan2
- ITIH5 | c.2404G>A p.G802S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as COSV99905808; called by muse, mutect2, varscan2
- KIAA0408 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV100847077; called by muse, mutect2, varscan2
- KIAA1549L | c.1307G>C p.S436T (on ENST00000321505; = p.S733T on NM_012194.3) | Missense Mutation (SNP) | VAF 428/522 reads (82%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.202); catalogued as COSV99684479; called by muse, mutect2, varscan2
- KIRREL3 | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs767576175, COSV101375235; called by muse, mutect2, varscan2
- KLHL7 | c.412A>G p.K138E (on ENST00000339077 / NM_001031710.3; = p.K90E on NM_018846.5) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV100178434; called by muse, mutect2, varscan2
- LARP4B | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | catalogued as COSV100295692; called by muse, mutect2, varscan2
- LMNTD1 | c.939A>C p.Q313H | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.143); catalogued as COSV99280339; called by muse, mutect2, varscan2
- LRRTM1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV54445116, COSV99703215; called by muse, mutect2, varscan2
- LY6D | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1285372844, COSV100009295; called by muse, mutect2, varscan2
- MAGEB18 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1423143920, COSV100305636; called by muse, mutect2, varscan2
- MAGI1 | c.743A>G p.N248S | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100443170; called by muse, mutect2, varscan2
- MAP3K21 | c.1916A>G p.D639G | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV100786170; called by muse, mutect2, varscan2
- MAP4K1 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs778834269, COSV101204420; called by muse, mutect2, varscan2
- MMP21 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV100916696; called by muse, mutect2, varscan2
- MTUS2 | c.2192A>C p.K731T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV70918043, COSV70919467, COSV70920728; called by muse, mutect2, varscan2
- MUC7 | c.920C>G p.P307R | Missense Mutation (SNP) | VAF 20/209 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100512282, COSV100512389, COSV59219352; called by muse, mutect2, varscan2
- MYEF2 | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99982205; called by muse, mutect2, varscan2
- MYO1C | c.2836G>A p.A946T (on ENST00000648651 / NM_001080779.2; = p.A911T on NM_033375.5) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.499); catalogued as rs147835827; called by muse, mutect2, varscan2
- MYRIP | c.1395A>C p.E465D | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV100220052; called by muse, mutect2, varscan2
- NAAA | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99716145; called by muse, mutect2, varscan2
- NALCN | c.1980G>C p.E660D | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.08); catalogued as COSV99217827; called by muse, mutect2, varscan2
- NDST3 | c.1083A>C p.E361D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99631908; called by muse, mutect2, varscan2
- NEB | c.3455C>T p.A1152V | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV99428165; called by muse, mutect2
- NFATC2 | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV101044725; called by muse, mutect2, varscan2
- NKX2-3 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100755131; called by muse, mutect2, varscan2
- NLRC3 | c.3013C>T p.R1005W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1236058017, COSV100073439, COSV57087070; called by muse, mutect2, varscan2
- NPTX2 | c.1128C>G p.F376L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.622); catalogued as COSV99675112; called by muse, mutect2, varscan2
- NRXN3 | c.3179A>C p.N1060T (on ENST00000335750 / NM_001330195.2; = p.N687T on NM_004796.6) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100209260; called by muse, mutect2, varscan2
- NSUN2 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371887249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP160 | c.2269C>G p.Q757E | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV101021639; called by muse, mutect2, varscan2
- NUP214 | c.5855G>A p.G1952E | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845396; called by muse, mutect2, varscan2
- OR4A16 | c.314T>G p.L105R | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.434); catalogued as COSV59043856, COSV59044552; called by muse, mutect2, varscan2
- OR52B2 | c.938A>C p.K313T | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.346); catalogued as COSV101603966; called by muse, mutect2, varscan2
- OR8B2 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as COSV100899503; called by muse, mutect2, varscan2
- PABPC3 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV55800541; called by muse, mutect2, varscan2
- PAPPA2 | c.1318C>A p.H440N | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV62788689; called by muse, mutect2, varscan2
- PCDH17 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs149002900, COSV64975035; called by muse, mutect2, varscan2
- PCDH9 | c.1367G>C p.R456T | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as COSV100123618; called by muse, mutect2, varscan2
- PCDHA10 | c.986T>C p.M329T | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as rs374158544; called by muse, mutect2, varscan2
- PCDHB4 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.01); catalogued as COSV99522508; called by muse, mutect2, varscan2
- PCDHGA3 | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53987367, COSV99547266; called by muse, mutect2, varscan2
- PDYN | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 49/285 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138498390, COSV54101109; called by muse, mutect2, varscan2
- PEG3 | c.3785C>A p.A1262D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.659); catalogued as COSV99690432; called by muse, mutect2, varscan2
- PHLPP2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as COSV100673836; called by muse, mutect2, varscan2
- PNPLA4 | c.427A>C p.S143R | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101124429; called by muse, mutect2, varscan2
- PPFIA2 | c.165C>G p.S55R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.219); catalogued as COSV100335335; called by muse, mutect2, varscan2
- PPFIA3 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.246); catalogued as rs1013294744, COSV100495310; called by muse, mutect2
- PPP2R3A | c.1456A>G p.K486E | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV53868068; called by muse, mutect2, varscan2
- PRKCQ | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV99577901; called by muse, mutect2, varscan2
- PROS1 | c.1696A>G p.S566G | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as COSV101260849; called by muse, mutect2, varscan2
- PRRX1 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 29/67 reads (43%) | catalogued as COSV99510347; called by muse, mutect2, varscan2
- PTPN13 | c.3718C>T p.R1240W (on ENST00000411767 / NM_080683.3; = p.R1221W on NM_006264.3) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs894216631, COSV57403353; called by muse, mutect2
- PTPN20 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.569); catalogued as rs1160630204; called by muse, mutect2, varscan2
- PWP1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101338860; called by muse, mutect2, varscan2
- PZP | c.3595G>C p.V1199L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.14); catalogued as rs767201731, COSV99739512; called by muse, mutect2, varscan2
- QRFPR | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100543980; called by muse, mutect2, varscan2
- RASGRP4 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs368971000, COSV99498785; called by muse, mutect2, varscan2
- RBBP8 | c.1063A>G p.K355E | Missense Mutation (SNP) | VAF 42/347 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200956310, COSV59093143; called by mutect2, varscan2
- SCN7A | c.1406A>C p.K469T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs917164746, COSV69270701; called by muse, mutect2, varscan2
- SELL | c.959G>C p.G320A (on ENST00000650983; = p.G307A on NM_000655.5) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV52550049, COSV52550522; called by muse, mutect2
- SFTPA1 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV100957201; called by muse, mutect2, varscan2
- SLC18A3 | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.107); catalogued as COSV100340921; called by muse, mutect2, varscan2
- SLC24A5 | c.841A>G p.S281G | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV99982200; called by muse, mutect2, varscan2
- SLC25A21 | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100492520; called by muse, mutect2, varscan2
- SLC44A2 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV59836376; called by muse, mutect2, varscan2
- SMAD1 | c.952A>G p.N318D | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100129943; called by muse, mutect2
- SOGA1 | c.1164G>T p.L388F | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99415334; called by muse, mutect2, varscan2
- SORCS2 | c.2777C>T p.T926M | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.832); catalogued as rs373844040; called by muse, mutect2, varscan2
- SPEG | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV100405690; called by muse, mutect2, varscan2
- SPON2 | c.736C>G p.Q246E | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV99335353; called by muse, mutect2, varscan2
- ST6GAL1 | c.566C>G p.S189* | Nonsense Mutation (SNP) | VAF 42/245 reads (17%) | catalogued as COSV99399664; called by muse, mutect2, varscan2
- TAF6L | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs138817605; called by muse, mutect2, varscan2
- TANC2 | c.4628G>A p.R1543Q | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as rs773193935, COSV67340609; called by muse, mutect2, varscan2
- TBC1D15 | c.182C>A p.S61Y | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100042282, COSV59850824; called by muse, mutect2, varscan2
- TBC1D32 | c.2136T>A p.N712K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV99251334; called by muse, mutect2, varscan2
- TCERG1L | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100894593, COSV64047352; called by muse, mutect2, varscan2
- TJP1 | c.3839A>C p.E1280A | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.445); catalogued as COSV100633180; called by muse, mutect2, varscan2
- TM9SF3 | c.1626G>A p.K542= | Splice Region (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100951888; called by muse, mutect2, varscan2
- TNFRSF19 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as rs372905269, COSV99947737; called by muse, mutect2, varscan2
- TNIP3 | c.458A>C p.E153A | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV99284841; called by muse, mutect2, varscan2
- TNR | c.1240+1G>A p.X414_splice | Splice Site (SNP) | VAF 9/85 reads (11%) | catalogued as rs1245352495, COSV54912763; called by muse, mutect2, varscan2
- TP53BP1 | c.4987G>A p.V1663I | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99781563; called by muse, mutect2, varscan2
- TRHDE | c.2567T>C p.V856A | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV53871658; called by muse, mutect2, varscan2
- TRPC4AP | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV99328919; called by muse, mutect2, varscan2
- TSC2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs45517126, CM014749; ClinVar: likely benign / not provided / benign; called by muse, mutect2, varscan2
- TSHZ2 | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776055494, COSV100296790; called by muse, mutect2, varscan2
- TSPYL5 | c.440A>G p.K147R | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs368313628; called by muse, mutect2
- TTF2 | c.1921T>C p.S641P | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101037864; called by muse, mutect2
- TTN | c.91014G>C p.Q30338H (on ENST00000591111; = p.Q22914H on NM_003319.4) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | PolyPhen benign (0.003); catalogued as COSV100630548; called by muse, mutect2, varscan2
- TTN | c.42310G>C p.E14104Q (on ENST00000591111; = p.E6680Q on NM_003319.4) | Missense Mutation (SNP) | VAF 32/216 reads (15%) | PolyPhen probably damaging (0.997); catalogued as COSV100630552; called by muse, mutect2, varscan2
- TYW5 | c.832A>C p.I278L | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100178995; called by muse, mutect2
- UCKL1 | c.1364C>A p.T455N | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100694303; called by muse, mutect2
- UHRF1BP1L | c.2830A>G p.K944E | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV99692179; called by muse, mutect2
- USP53 | c.2443G>C p.D815H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.145); catalogued as COSV99918069; called by muse, mutect2
- WDFY3 | c.9145A>G p.T3049A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV55708318; called by muse, mutect2, varscan2
- XDH | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs751261129, COSV65146745; called by muse, mutect2, varscan2
- ZBED9 | c.1801T>G p.L601V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV101509398; called by muse, mutect2, varscan2
- ZC3H8 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.062); catalogued as COSV99735687; called by muse, mutect2, varscan2
- ZDHHC14 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as rs370693708; called by muse, mutect2, varscan2
- ZDHHC24 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100130713; called by muse, mutect2
- ZFPM2 | c.2916A>G p.I972M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV101023579; called by muse, mutect2, varscan2
- ZNF184 | c.2053C>G p.L685V | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs748974450, COSV99280087; called by muse, mutect2, varscan2
- ZNF276 | c.1549C>T p.R517* (on ENST00000443381 / NM_001113525.2; = p.R442* on NM_152287.4) | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as rs763134179, COSV57066518; called by muse, mutect2, varscan2
- ZNF320 | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101206941; called by muse, mutect2, varscan2
- ZNF501 | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); catalogued as COSV101247023, COSV101247158; called by muse, mutect2, varscan2
- ZNF551 | c.712C>A p.L238I | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV99990359; called by muse, mutect2, varscan2
- ZNRF3 | c.2651C>T p.A884V (on ENST00000544604 / NM_001206998.2; = p.A784V on NM_032173.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV100239021; called by muse, mutect2, varscan2
- ZSCAN29 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369750925; called by muse, mutect2, varscan2
- CSMD1 | c.10320G>C p.V3440= (on ENST00000520002; = p.V3439= on NM_033225.6) | Splice Region (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- HDLBP | c.2440_2442dup p.H814dup | In Frame Ins (INS) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
- IGKV3-11 | c.303A>C p.E101D | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- KIR2DL1 | c.712A>C p.T238P | Missense Mutation (SNP) | VAF 44/462 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, varscan2
- MGAT5 | c.267_271delinsC p.L89Ffs*74 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | called by pindel, varscan2*
- MROH8 | c.1775_1777del p.R593del | In Frame Del (DEL) | VAF 46/366 reads (13%) | called by pindel, varscan2
- NRAS | c.510dup p.L171Tfs*5 | Frame Shift Ins (INS) | VAF 65/193 reads (34%) | called by mutect2, pindel, varscan2
- PPP1R11 | c.178+3_178+6del p.X60_splice | Splice Site (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel
- PRAMEF14 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, varscan2
- PRAMEF15 | c.1075T>G p.L359V | Missense Mutation (SNP) | VAF 125/556 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PSMB9 | c.204_206del p.A70del | In Frame Del (DEL) | VAF 8/75 reads (11%) | called by mutect2, pindel, varscan2
- VN1R5 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2
- ADSS2 | c.37C>T p.L13= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV63696018; called by muse, mutect2, varscan2
- AHNAK | c.12534C>T p.D4178= | Silent (SNP) | VAF 55/337 reads (16%) | catalogued as rs768357013, COSV57203097; called by muse, mutect2, varscan2
- AKAP11 | c.2553A>G p.K851= | Silent (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- ANGPT1 | c.723C>T p.T241= | Silent (SNP) | VAF 24/147 reads (16%) | catalogued as COSV99864283; called by muse, mutect2, varscan2
- BNC1 | c.426C>T p.Y142= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as rs745313602, COSV100597019; called by muse, mutect2, varscan2
- CHRNB3 | c.1290C>T p.F430= | Silent (SNP) | VAF 75/236 reads (32%) | catalogued as COSV99251511; called by muse, mutect2, varscan2
- CORO1B | c.282C>T p.N94= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as rs774302969, COSV100396781; called by muse, mutect2, varscan2
- CSAD | c.588G>A p.K196= (on ENST00000444623 / NM_001244705.2; = p.K223= on NM_015989.5) | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV99915052; called by muse, mutect2, varscan2
- CSMD1 | c.4206C>G p.T1402= (on ENST00000520002; = p.T1401= on NM_033225.6) | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100153861; called by muse, varscan2
- DCC | c.3765G>A p.T1255= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as rs935877388, COSV71436692; called by muse, mutect2, varscan2
- DISP3 | c.2118C>T p.R706= | Silent (SNP) | VAF 49/245 reads (20%) | catalogued as rs373832249; called by muse, mutect2, varscan2
- DLGAP2 | c.1263C>T p.T421= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs374538901; called by muse, mutect2, varscan2
- E2F5 | c.423A>G p.E141= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV99809770; called by muse, mutect2, varscan2
- ELL | c.1161G>T p.R387= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99443776; called by muse, mutect2, varscan2
- EPHA6 | c.678A>C p.S226= | Silent (SNP) | VAF 105/274 reads (38%) | catalogued as COSV101065593; called by muse, mutect2, varscan2
- FAIM2 | c.117G>A p.E39= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV100277709, COSV57739046; called by muse, mutect2
- FAT3 | c.12810G>A p.S4270= | Silent (SNP) | VAF 58/316 reads (18%) | catalogued as rs768838868, COSV53120559; called by muse, mutect2, varscan2
- FBXW11 | c.900T>G p.S300= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV99441534; called by muse, mutect2, varscan2
- GABRA6 | c.507T>C p.A169= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as rs1400096249, COSV99195204; ClinVar: likely benign; called by muse, mutect2
- GPR179 | c.6084C>A p.I2028= (on ENST00000621958; = p.I2027= on NM_001004334.4) | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as rs771332102; called by muse, mutect2, varscan2
- HYAL2 | c.1296C>G p.G432= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100753963; called by muse, mutect2, varscan2
- IL22RA2 | c.396C>T p.Y132= | Silent (SNP) | VAF 21/199 reads (11%) | catalogued as rs762290472, COSV99760835; called by muse, mutect2, varscan2
- ITM2B | c.747C>T p.F249= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs765077508, COSV66034801; called by muse, mutect2, varscan2
- KCNG1 | c.558C>T p.D186= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV100857181, COSV65370498; called by muse, mutect2
- KLHL1 | c.1332T>G p.T444= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV100917428; called by muse, mutect2
- LRRK1 | c.3345A>G p.G1115= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs1275390929, COSV99443249; called by muse, mutect2, varscan2
- MDN1 | c.9822G>A p.L3274= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV101021843; called by muse, mutect2, varscan2
- MLLT6 | c.3048G>A p.A1016= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs778177674; called by muse, mutect2, varscan2
- MTHFD1 | c.759G>C p.V253= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99386544, COSV99387394; called by muse, mutect2, varscan2
- MUC5B | c.7041C>T p.A2347= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs766599670, COSV101500747; called by muse, mutect2, varscan2
- MUC5B | c.9555C>T p.S3185= | Silent (SNP) | VAF 63/157 reads (40%) | catalogued as rs1238201064, COSV101500786; called by muse, mutect2, varscan2
- MUC5B | c.11676C>T p.S3892= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV101500787; called by muse, mutect2, varscan2
- MYBPC3 | c.132C>T p.R44= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs377579620; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MYO9A | c.496C>T p.L166= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as rs1333710114, COSV100614338; called by muse, mutect2, varscan2
- OR10T2 | c.567C>T p.A189= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100555130; called by muse, mutect2, varscan2
- OR2L8 | c.243A>T p.A81= | Silent (SNP) | VAF 134/409 reads (33%) | catalogued as COSV100594324; called by muse, mutect2, varscan2
- OR6N1 | c.160C>A p.R54= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV58647450, COSV58648204; called by muse, mutect2, varscan2
- PEG3 | c.2034T>C p.T678= | Silent (SNP) | VAF 18/183 reads (10%) | catalogued as COSV55642079, COSV99690435; called by muse, mutect2, varscan2
- PKD2L1 | c.108A>G p.R36= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as COSV100559459; called by muse, mutect2, varscan2
- PRDM16 | c.1137C>T p.S379= | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as rs748323433, COSV54592591, COSV99578929; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCAMP5 | c.144C>T p.S48= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs765221844, COSV100723859; called by muse, mutect2, varscan2
- SCARF1 | c.1716G>A p.T572= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs763226742, COSV99556780; called by muse, mutect2, varscan2
- SF1 | c.1047C>T p.P349= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs191725407; called by muse, mutect2, varscan2
- SLC39A12 | c.303T>C p.N101= | Silent (SNP) | VAF 64/146 reads (44%) | catalogued as COSV101070183; called by muse, mutect2, varscan2
- SP110 | c.519G>A p.S173= | Silent (SNP) | VAF 52/197 reads (26%) | catalogued as rs114550400; called by muse, mutect2, varscan2
- SPANXB1 | c.108T>C p.T36= | Silent (SNP) | VAF 56/386 reads (15%) | called by muse, mutect2, varscan2
- STEAP2 | c.627T>C p.F209= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as COSV99840709; called by muse, mutect2, varscan2
- SYTL2 | c.978G>T p.L326= | Silent (SNP) | VAF 40/228 reads (18%) | catalogued as COSV100315010; called by muse, mutect2, varscan2
- TECTA | c.1593C>T p.D531= | Silent (SNP) | VAF 65/259 reads (25%) | catalogued as rs374231752, COSV50747367; ClinVar: likely benign; called by muse, mutect2, varscan2
- TKTL2 | c.138G>A p.A46= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs764116442, COSV54920294; called by muse, mutect2, varscan2
- TMEM176B | c.72C>T p.N24= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs181849033; called by muse, mutect2, varscan2
- TMEM26 | c.555G>A p.A185= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as rs1209166913, COSV99515852; called by muse, mutect2, varscan2
- TTN | c.96756G>A p.E32252= (on ENST00000591111; = p.E24828= on NM_003319.4) | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV100630542; called by muse, mutect2, varscan2
- VSIG2 | c.633C>G p.S211= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV99423495; called by muse, mutect2, varscan2
- WDR72 | c.3201A>G p.Q1067= | Silent (SNP) | VAF 32/259 reads (12%) | catalogued as rs764838973, COSV100855103; called by muse, varscan2
- XRCC2 | c.681C>T p.L227= | Silent (SNP) | VAF 37/168 reads (22%) | catalogued as COSV100831696; called by muse, mutect2, varscan2
- ANKMY1 | c.-51G>T | 5'UTR (SNP) | VAF 72/260 reads (28%) | catalogued as rs966074347, COSV99803267; called by muse, mutect2, varscan2
- FOLH1B | n.1573A>C | RNA (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- TRAV36DV7 | chr14:22222209 C>G | 5'Flank (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- TUBB7P | n.210G>A | RNA (SNP) | VAF 21/105 reads (20%) | catalogued as rs1454527068; called by muse, mutect2, varscan2
